Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A8S8, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A8S8-01A (Primary Tumor).

[page 1 of 3]
PROSTATE AND OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

TUMOR PROCUREMENT:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 5 = 9

TERTIARY PATTERN NOT PRESENT

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

1: ___%

2: ___%

3: ___%

4: 90%

5: 10%

TUMOR LOCATION

APEX

BASE

ANTERIOR

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

NON-FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

RIGHT BASE

ANTERIOR

LEFT

POSTERIOR

LEFT

SEMINAL VESICAL INVASION

ABSENT

SURGICAL MARGINS

INVOLVED BY INVASIVE CARCINOMA

APEX (LEFT POSTERIOR)

NATURE OF POSITIVE MARGINS

IN AREAS OF EXTRA-PROSTATIC EXTENSION

EXTENT OF POSITIVE MARGINS

MULTIFOCAL

MILLIMETRIC EXTENT OF POSITIVE MARGINS: NOT REPORTED

GLEASON GRADE OF CARCINOMA PRESENT AT THE POSITIVE MARGINS

NOT REPORTED

LYMPHOVASCULAR INVASION

NOT REPORTED

PERINEURAL INVASION

PRESENT

TUMOR VOLUME

PROPORTION OF PROSTATE INVOLVED BY CARCINOMA: 50%

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

RIGHT OBTURATOR

NUMBER OF NODES IDENTIFIED: 6_

*Gleason 4+4 pw path
discrepancy form*

ICD-O-3

*Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9*

J 4/22/14

[page 2 of 3]
NUMBER OF NODES INVOLVED BY METASTASIS: 0__

LEFT OBTURATOR

NUMBER OF NODES IDENTIFIED: 4__

NUMBER OF NODES INVOLVED BY METASTASIS: _0__

ADDITIONAL PATHOLOGIC FINDINGS

HIGH-GRADE PROSTATIC INTRA-EPITHELIAL NEOPLASIA

PATHOLOGICAL STAGING

pT3a

pN0

pMX

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

1/1/00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	ACINAR ADENOCARCINOMA GLEASON 4+5=9	Provide the diagnosis/histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	ACINAR ADENOCARCINOMA GLEASON 4+4=8	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	PROVIDED SAMPLE SHOWED ONLY PATTERN 4 (SAMPLING ISSUE)	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file eb06af13-9f47-418d-823e-96a7d7bf3562 (TCGA-YL-A8S8.6D4A3078-4C6B-4E94-B859-CCA473B09CF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).